Surgical pathology report (de-identified scan), TCGA case TCGA-EP-A2KC, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Christiana Healthcare, specimen TCGA-EP-A2KC-01A (Primary Tumor).

Final Surgical Pathology Report

1C0-0-3

Carcinoma, hepatocellular, NOS

8170/3

Site: liver C22.0

Procedure:

Diagnosis

- A. Right coronary ligament, biopsy:
Dense fibrous connective tissue.
- B. Liver, segment 7, resection:
Hepatocellular carcinoma, poorly differentiated, 3.0 cm, margins
uninvolved.
Cirrhosis.

Microscopic Description:

Microscopic examination performed.

- A. Sections of the right coronary ligament demonstrate dense fibrous
connective tissue.
- B. Histologic type: Hepatocellular carcinoma
Histologic grade: poorly differentiated
Tumor size: 3.0 cm
Primary tumor (pT): pT1
Margins of resection: Negative
Vascular invasion: Not identified
Regional lymph nodes (pN): None submitted with this specimen, pNX
Distant metastasis (pM): Cannot be evaluated by the specimen, pMX
Other findings: The carcinoma is arising in a background of cirrhosis.

Specimen

- A. Right coronary ligament
B. Hepatoma segment 7

Clinical Information

Hepatocellular cancer

Gross Description

- A. Received in formalin labeled "right coronary ligament" is an
irregular, 1.0 x 0.3 x 0.3 cm fragment of rubbery tan-pink-gold tissue.
The specimen is inked, sectioned, and entirely submitted in one block.

- B. Received fresh for tissue procurement labeled "hepatoma segment 7"
is a wedge shaped, 7.8 x 6.8 x 4.0 cm portion of liver parenchyma. The
capsule is diffusely bosselated tan-pink-gold. The cauterized margin
of resection is inked black and the specimen is sectioned. There is a
moderately well circumscribed, 3.0 x 2.9 x 2.5 cm pale yellow-white to
tan gold nodular lesion which is present within 0.05 cm of the capsular
surface and 1.5 cm of the inked margin of resection. The remaining
parenchyma is finely nodular tan gold-pink. A portion of tumor and a
portion of normal parenchyma are submitted for tissue procurement. RS
8.

Summary: 1 through 4-tumor to capsular surface; 5 and 6-tumor to inked
margin of resection; 7 and 8 random from remainder.

Source: NCI Genomic Data Commons file 455b1ab5-51eb-4d92-82e5-359d10c6758e (TCGA-EP-A2KC.F45A4E99-3856-4455-BF21-B767A0A4FA82.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).